Gene-level copy-number profile of tumor specimen TCGA-B6-A0RL-01A from TCGA case TCGA-B6-A0RL, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIA; Age at diagnosis: 60.9 years (22,238 days).
Specimen TCGA-B6-A0RL-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.6217eb8d-0841-471a-aaba-b21023267625.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-B6-A0RL-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 813 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/101f1b49-97da-425a-96d8-e3ead5fdbb5f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 17,486; copy number 2: 35,997; copy number 3: 5,362; copy number 4: 302; copy number 5: 16; copy number 6: 100; copy number 7: 233; copy number 8: 64; copy number 9: 45; copy number 10: 56; copy number 11: 98; copy number 15: 45; copy number 16: 1; copy number 20: 5.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-B6-A0RL-01A-11D-A087-01): tumor purity 0.91, ploidy 1.89, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 663 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:161,931,199–163,289,096, 16 genes, copy number 7: RPEP5, DPP4, DPP4-DT, TIMM8AP1, EIF3EP2, AC008063.1, GCG, AC007750.1, FAP, IFIH1, GCA, KCNH7, RNA5SP109, KCNH7-AS1, RPL7P61, RNU6-627P.
- chr2:176,495,255–176,819,180, 1 gene, copy number 7 (within-gene range 1–7): LINC01117.
- chr2:176,629,572–178,451,512, 45 genes, copy number 7 (within-gene range 1–7): LINC01116, RNU6ATAC14P, AC092162.2, FUCA1P1, AC092162.1, AC092162.3, AC073636.1, RNU6-187P, AC074286.1, AC079305.2, RNA5SP112, STUB1P1, Y_RNA, KRT8P40, HNRNPA3, MIR4444-1, NFE2L2, DNAJC19P5, MIR3128, AC079305.1, AC019080.1, AC019080.3, AC019080.4, MIR6512, AC019080.5, H3P7, AC019080.2, AGPS, TTC30B, AC073834.1, TTC30A, PDE11A, PDE11A, PDE11A-AS1, AC011998.2, API5P2, SDHDP5, RNU6-629P, CYCTP, AC011998.1, RBM45, RNU5E-9P, OSBPL6, CHROMR, PRKRA.
- chr2:194,129,354–198,572,581, 58 genes, copy number 7 (within-gene range 1–7): GLULP6, HNRNPA1P47, LINC01821, AC106883.1, AC073973.1, Metazoa_SRP, AC006196.1, LINC01790, AC010983.1, AC104823.1, AC064834.1, RNU6-169P, LINC01825, LINC01827, SLC39A10, AHCYP5, RNU6-915P, DNAH7, E2F3P2, AC114760.1, STK17B, AC114760.2, HECW2, HECW2-AS1, RN7SL820P, AC068544.2, CCDC150, AC068544.1, GTF3C3, C2orf66, AC012486.1, PGAP1, ANKRD44, HNRNPA3P15, RPL4P7, ANKRD44-AS1, ANKRD44-IT1, ATP5MC2P3, AC010746.2, NPM1P46, SF3B1, AC010746.1, RNU6-1029P, COQ10B, HSPD1, HSPE1, HSPE1-MOB4, MOB4, AC020550.1, RFTN2, AC020550.2, AC011997.1, MARS2, BOLL, PLCL1, AC011997.2, AC020719.1, LINC01923.
- chr2:199,269,500–199,471,266, 2 genes, copy number 6 (within-gene range 1–6): SATB2, AC016746.1.
- chr8:31,639,222–43,674,591, 232 genes, copy number 6–11 (within-gene range 1–11) (broad region; genes not listed).
- chr10:74,744,386–78,178,186, 59 genes, copy number 5–6: FAM32CP, AC063962.1, KAT6B, AC018511.2, AC018511.1, DUSP29, AC018511.6, PPIAP13, DUSP13, SAMD8, RPS26P42, VDAC2, COMTD1, ZNF503-AS1, RPL39P25, HMGA1P5, AC010997.3, AC010997.1, SPA17P1, ZNF503, ZNF503-AS2, AC010997.5, AC010997.4, AC010997.2, LRMDA, AC010997.6, MIR606, AL589863.2, AL589863.1, AL731568.1, RN7SL518P, RNU6-673P, AC012048.1, AC013286.1, AC024603.1, AC013738.1, ATP5MC1P8, KCNMA1, KCNMA1-AS1, KCNMA1-AS2, AL731575.1, KCNMA1-AS3, COX6CP15, RNA5SP321, AL731556.1, AL731556.2, RNU6-1266P, IMPDH1P5, AL450306.1, DLG5, AL391421.1, RN7SL284P, DLG5-AS1, H2AZP5, Metazoa_SRP, POLR3A, RPS24, GNAI2P2, AL731555.1.
- chr11:60,056,587–61,295,316, 45 genes, copy number 9 (within-gene range 3–9): MS4A3, AP000790.2, MS4A2, LINC02705, MS4A6A, MS4A4A, MS4A4E, MIR6503, MS4A6E, MS4A7, MS4A14, MS4A5, MS4A1, MS4A12, MS4A13, MS4A19P, LINC00301, MS4A8, MS4A18, MS4A15, MS4A10, AP000777.1, AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1, PGA3, PGA4, AP003037.1, PGA5, VWCE.
- chr11:68,612,899–70,436,584, 55 genes, copy number 10: AP003096.1, GAL, TESMIN, CPT1A, LINC02701, MRPL21, IGHMBP2, AP000808.1, MRGPRD, AP003071.4, AP003071.3, MRGPRF, MRGPRF-AS1, TPCN2, AP003071.5, MIR3164, AP003071.1, AP003071.2, SMIM38, MYEOV, IFITM9P, AP005233.2, AP005233.1, AP000439.2, AP000439.1, AP000439.3, LINC02747, LINC01488, CCND1, LTO1, FGF19, DNAJB6P5, FGF4, FGF3, AP007216.1, AP007216.2, AP003555.2, AP003555.1, LINC02753, LINC02584, RNU6-1175P, ANO1, AP000879.2, ANO1-AS1, FADD, AP000879.1, PPFIA1, H2AZP4, AP002336.2, MIR548K, AP002336.1, AP002336.3, AP000487.2, AP000487.1, CTTN.
- chr11:70,477,277–70,477,592, 1 gene, copy number 10: AP001271.1.
- chr11:73,157,946–74,398,433, 43 genes, copy number 15: AP002761.2, AP002761.1, P2RY2, AP002761.4, OR8R1P, P2RY6, AP002761.3, ARHGEF17, RELT, AP000763.4, FAM168A, AP000763.3, AP000763.1, AP000763.2, HMGN2P38, AP000860.1, PLEKHB1, RAB6A, AP002993.1, AP002770.1, MRPL48, RN7SKP243, CCDC58P5, COA4, PAAF1, ARPC3P4, DNAJB13, AP003717.1, UCP2, AP003717.4, AP003717.2, AP003717.3, UCP3, C2CD3, AP002392.1, PPME1, RNA5SP343, AP000577.2, P4HA3, AP000577.1, P4HA3-AS1, PGM2L1, HNRNPA1P40.
- chr11:74,398,825–74,416,379, 2 genes, copy number 15: AP001085.1, MIR548AL.
- chr11:75,717,838–82,718,299, 104 genes, copy number 6–20 (within-gene range 1–20) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 16,859. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
